Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA30, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA30-01A (Primary Tumor).

Male
Surgery Date:

DIAGNOSIS:

A. Peritoneum, biopsy: Adipose tissue; negative for tumor.

B. Lymph node, perigastric, biopsy: A single lymph node is negative for tumor.

C. Liver, segments I-IV, wedge resections: Cholangiocarcinoma, grade 3 of 4, is identified forming a single mass (11.0 x 10.3 x 6.6 cm) that is confined to hepatic parenchyma. The tumor growth pattern is mixed mass-forming and periductal infiltrating. The hepatic parenchymal resection margin is negative for tumor (minimum tumor free margin 0.6 cm). The bile duct margin is negative for invasive carcinoma and carcinoma in situ. Major vessel invasion is absent. Microscopic invasion is absent. No lymph node metastasis is identified in 2 regional lymph nodes. A bile duct hamartoma was identified. with available surgical material [AJCC pT₁N0] (7th edition, 2010).

ICD-O 3

Cholangiocarcinoma 8160/3
Site: Intrahepatic bile duct C22.1
JN 318114

Source: NCI Genomic Data Commons file 40d0cb65-ce40-451f-9cda-866066c4f892 (TCGA-W5-AA30.9C2BEED7-DB8C-4BFE-920A-DD716B884777.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).